Somatic mutation profile of tumor specimen TCGA-CS-4942-01A (aliquot TCGA-CS-4942-01A-01D-1468-08) from TCGA case TCGA-CS-4942, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 44.6 years (16,297 days).
Specimen TCGA-CS-4942-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c9b69aaa-d2d2-4b51-940c-bdf8361a4623.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CS-4942-10A (Blood Derived Normal), aliquot TCGA-CS-4942-10A-01D-1468-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b0ab544f-bef6-4e79-ba7f-2a2a2ce67e5a

The open-access MAF lists 23 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 18, Silent 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 37/122 reads (30%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.824G>T p.C275F | Missense Mutation (SNP) | VAF 53/64 reads (83%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANOS1 | c.638A>G p.E213G | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52923080; called by muse, mutect2, varscan2
- ASPM | c.6166G>C p.A2056P | Missense Mutation (SNP) | VAF 101/322 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV54128509, COSV54133661; called by muse, mutect2, varscan2
- BCOR | c.3392G>A p.R1131Q | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs758883383, COSV60709202, COSV60712636; called by muse, mutect2, varscan2
- CEP170 | c.2984G>A p.R995H | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs375934140; called by mutect2, varscan2
- F2 | c.1729C>T p.P577S | Missense Mutation (SNP) | VAF 56/169 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.297); catalogued as COSV56370809; called by muse, mutect2, varscan2
- FRMD7 | c.799T>C p.F267L | Missense Mutation (SNP) | VAF 152/446 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53747583; called by muse, mutect2, varscan2
- GLRB | c.872A>G p.N291S | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs1269794898, COSV52419632; called by muse, mutect2
- HLA-DRA | c.278C>A p.A93D | Missense Mutation (SNP) | VAF 84/248 reads (34%) | SIFT tolerated (0.62); PolyPhen benign (0.046); catalogued as COSV66622921; called by muse, mutect2, varscan2
- PDE1C | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 91/364 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.398); catalogued as rs771510500, COSV58504644; called by muse, mutect2, varscan2
- PIK3R1 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 24/225 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as rs765008592, COSV57124539; called by muse, mutect2, varscan2
- POC1A | c.847G>A p.G283R | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56592435; called by muse, mutect2, varscan2
- SLC9A4 | c.2332A>G p.T778A | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as COSV54836671; called by muse, mutect2, varscan2
- SYNPO2L | c.2756T>C p.I919T (on ENST00000394810 / NM_001114133.3; = p.I695T on NM_024875.5) | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as COSV65738123; called by muse, mutect2, varscan2
- TBC1D9 | c.1934A>G p.D645G | Missense Mutation (SNP) | VAF 110/291 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71308012; called by muse, mutect2, varscan2
- USP51 | c.715T>C p.C239R | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72351799; called by muse, mutect2, varscan2
- YES1 | c.118T>C p.S40P | Missense Mutation (SNP) | VAF 128/328 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV58851318; called by muse, mutect2, varscan2
- ACTR3 | c.777C>T p.I259= | Silent (SNP) | VAF 58/139 reads (42%) | catalogued as COSV54302509; called by muse, mutect2, varscan2
- CDC20B | c.492C>T p.C164= | Silent (SNP) | VAF 29/95 reads (31%) | catalogued as COSV57054608; called by muse, mutect2, varscan2
- DGKH | c.1669C>T p.L557= | Silent (SNP) | VAF 8/142 reads (6%) | catalogued as rs894265443, COSV54936378; called by muse, mutect2
- LAMB2 | c.4662C>T p.H1554= | Silent (SNP) | VAF 40/118 reads (34%) | catalogued as COSV59735578; called by muse, mutect2, varscan2
- POLR1A | c.534C>T p.G178= | Silent (SNP) | VAF 45/145 reads (31%) | catalogued as rs199538363; called by muse, mutect2, varscan2
